Somatic mutation profile of tumor specimen C3L-01865-01 (aliquot CPT0392260006) from CPTAC case C3L-01865, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hereditary leiomyomatosis & RCC-associated renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.9 years (26,260 days).
Specimen C3L-01865-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c794bcc1-e66f-4e6e-8066-34a7a381537f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01865-31 (Blood Derived Normal), aliquot CPT0392340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dfe628b-9294-4eb8-b675-e6cab29d783a

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Frame Shift Del 8, Silent 4, Nonsense Mutation 3, 5'Flank 2, 5'UTR 2, Frame Shift Ins 2, Intron 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOCAD | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264369680; called by muse, mutect2, varscan2
- KANK3 | c.934del p.R312Efs*29 | Frame Shift Del (DEL) | VAF 55/275 reads (20%) | catalogued as COSV58361166; called by mutect2, pindel, varscan2
- OPCML | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs746902700, COSV100101632; called by muse, mutect2, varscan2
- PTCH1 | c.3544C>A p.P1182T | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV59498627; called by muse, mutect2, varscan2
- UNC93B1 | c.1092C>T p.G364= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as rs202181767, COSV57099681; called by muse, mutect2
- AASS | c.1276del p.M426* | Frame Shift Del (DEL) | VAF 41/265 reads (15%) | called by mutect2, pindel, varscan2
- ACAN | c.2783G>A p.W928* | Nonsense Mutation (SNP) | VAF 25/128 reads (20%) | called by muse, varscan2
- ARID1B | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ATP6AP1 | c.1307T>A p.M436K | Missense Mutation (SNP) | VAF 99/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- B3GNT2 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA1I | c.1674T>G p.H558Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAD | c.4987G>A p.E1663K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDC42BPA | c.2836C>T p.H946Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CERK | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPP1 | c.1735G>A p.G579R (on ENST00000676605; = p.G538R on NM_024790.6) | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FAM104A | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FAM193A | c.2820dup p.P941Afs*3 | Frame Shift Ins (INS) | VAF 27/177 reads (15%) | called by mutect2, pindel, varscan2
- FARP1 | c.2107C>G p.H703D | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KDM6B | c.4793A>G p.Y1598C | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KIF1B | c.375del p.E125Dfs*18 | Frame Shift Del (DEL) | VAF 61/291 reads (21%) | called by mutect2, pindel, varscan2
- LIPE | c.3084_3090del p.L1029Rfs*38 | Frame Shift Del (DEL) | VAF 72/365 reads (20%) | called by mutect2, pindel, varscan2
- LMO7 | c.4543C>T p.Q1515* (on ENST00000357063; = p.Q1196* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- MLLT6 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTRES1 | c.622T>A p.L208M | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NDUFA6 | c.196dup p.M66Nfs*15 | Frame Shift Ins (INS) | VAF 50/261 reads (19%) | called by mutect2, pindel, varscan2
- NUDT4 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OSBPL5 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PARD3B | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIK3C2B | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTPN1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- PTPRF | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- RANGRF | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- SELENOH | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETDB1 | c.1536T>A p.S512R | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SREBF1 | c.905del p.K302Sfs*56 | Frame Shift Del (DEL) | VAF 79/367 reads (22%) | called by mutect2, pindel, varscan2
- STMND1 | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SVEP1 | c.8627_8628del p.N2876Rfs*69 | Frame Shift Del (DEL) | VAF 59/196 reads (30%) | called by mutect2, pindel, varscan2
- TBC1D14 | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TNFRSF1B | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TSC1 | c.790del p.L264Wfs*54 | Frame Shift Del (DEL) | VAF 38/255 reads (15%) | called by mutect2, pindel, varscan2
- TSC1 | c.281del p.G94Vfs*4 | Frame Shift Del (DEL) | VAF 95/332 reads (29%) | called by mutect2, pindel, varscan2
- USF3 | c.4163C>T p.P1388L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZBTB5 | c.1982A>G p.K661R | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ZC3H12A | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF480 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CD180 | c.345C>T p.F115= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs770454021; called by muse, mutect2, varscan2
- CFAP54 | c.813C>T p.L271= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- TGFB1 | c.570C>T p.S190= | Silent (SNP) | VAF 86/419 reads (21%) | catalogued as rs779809888, COSV55724799; called by muse, mutect2, varscan2
- TMEM81 | c.244C>T p.L82= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as rs1350974648; called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172392 G>C | 5'Flank (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- METTL2B | c.669+225G>A | Intron (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- PDZD7 | chr10:101016421 del C | 3'Flank (DEL) | VAF 20/138 reads (14%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34159801 G>A | 5'Flank (SNP) | VAF 50/347 reads (14%) | called by muse, mutect2, varscan2
- RO60 | c.-180T>A | 5'UTR (SNP) | VAF 97/365 reads (27%) | called by muse, mutect2, varscan2
- S100A11 | c.-49C>T | 5'UTR (SNP) | VAF 18/109 reads (17%) | called by muse, varscan2
- SYNRG | c.78-116T>A | Intron (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
